Somatic mutation profile of tumor specimen TCGA-XM-A8RE-01A (aliquot TCGA-XM-A8RE-01A-11D-A423-09) from TCGA case TCGA-XM-A8RE, project TCGA-THYM (Thymoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Thymoma, type AB, NOS; Tissue or organ of origin: Thymus; Age at diagnosis: 54.5 years (19,903 days).
Specimen TCGA-XM-A8RE-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1495ffb4-b853-4156-bebb-4f8d0f6ef7c3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-XM-A8RE-10A (Blood Derived Normal), aliquot TCGA-XM-A8RE-10A-01D-A426-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a130dec7-8300-47cd-a373-f1adf8c09d4d

The open-access MAF lists 3 somatic variants for this specimen: 3 protein-altering or splice-affecting.
By variant classification: Missense Mutation 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MCF2 | c.2594G>A p.C865Y | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT tolerated (0.2); PolyPhen benign (0.005); called by muse, mutect2
- RNF112 | c.750T>A p.D250E | Missense Mutation (SNP) | VAF 3/25 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.63); called by muse, mutect2
- RNF26 | c.1148G>A p.C383Y | Missense Mutation (SNP) | VAF 3/23 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
